Gene-level copy-number profile of tumor specimen TCGA-34-5928-01A from TCGA case TCGA-34-5928, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 83.0 years (30,334 days).
Specimen TCGA-34-5928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.85abd0f8-f810-422f-8993-ac7bf786a2e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-5928-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af04a2fd-fe57-4d14-a5da-69f131a214c5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 2: 3; copy number 3: 19,158; copy number 4: 15,838; copy number 5: 3,255; copy number 6: 8,083; copy number 7: 5,415; copy number 8: 3,139; copy number 9: 1,050; copy number 10: 1,405; copy number 11: 1,571; copy number 12: 204; copy number 13: 583; copy number 14: 23; copy number 15: 37; copy number 26: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-5928-01A-11D-1816-01): tumor purity 0.4, ploidy 3.54, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:90,529,344–91,383,317, 13 genes (within-gene range 0–4): ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3.
- chr5:91,476,382–91,477,018, 1 gene: RAB5CP2.
- chr5:164,935,162–164,935,268, 1 gene: RNU6-209P.
- chr10:87,945,502–89,063,411, 26 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 13,435 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–153,785,821, 454 genes, copy number 9 (broad region; genes not listed).
- chr1:153,793,947–153,802,091, 1 gene, copy number 9: AL513523.2.
- chr1:209,428,817–248,919,946, 863 genes, copy number 11 (broad region; genes not listed).
- chr2:1,789,113–69,437,628, 1,103 genes, copy number 7 (broad region; genes not listed).
- chr2:69,516,751–69,520,174, 2 genes, copy number 7: RN7SL604P, SNORA36C.
- chr3:127,689,062–198,222,513, 1,259 genes, copy number 8–13 (within-gene range 6–13) (broad region; genes not listed).
- chr5:58,198–7,391,907, 151 genes, copy number 11 (broad region; genes not listed).
- chr5:7,830,378–45,895,970, 557 genes, copy number 11 (broad region; genes not listed).
- chr6:167,607–63,616,361, 1,556 genes, copy number 7–8 (broad region; genes not listed).
- chr7:70,972–62,275,678, 1,079 genes, copy number 8 (broad region; genes not listed).
- chr7:63,556,598–69,597,493, 184 genes, copy number 7–12 (broad region; genes not listed).
- chr7:70,837,738–109,999,624, 748 genes, copy number 8 (broad region; genes not listed).
- chr7:110,590,082–159,233,377, 965 genes, copy number 7 (broad region; genes not listed).
- chr8:35,235,475–35,796,550, 1 gene, copy number 8 (within-gene range 3–8): UNC5D.
- chr8:35,525,176–120,813,359, 1,275 genes, copy number 7–26 (broad region; genes not listed).
- chr8:121,954,640–145,066,685, 443 genes, copy number 9–15 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 9–10 (within-gene range 3–10) (broad region; genes not listed).
- chr11:34,049,967–39,261,213, 63 genes, copy number 7 (broad region; genes not listed).
- chr11:76,654,169–78,444,049, 51 genes, copy number 7 (within-gene range 3–7): AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2.
- chr17:22,671,433–28,614,185, 86 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:43,211,835–68,955,392, 828 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:12,865,202–13,996,443, 16 genes, copy number 7: LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,128,336, 2 genes, copy number 7: RPS3P1, AIMP1P1.
- chr22:15,290,718–40,636,719, 1,073 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
